Surgical pathology report (de-identified scan), TCGA case TCGA-DD-A73A, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-A73A-01A (Primary Tumor).

Surgical Pathology

Requested By:

SLIDE DISPOSITION:

DIAGNOSIS:

A. Liver, caudate lobe, resection: Hepatocellular carcinoma, moderately differentiated, forming a single mass, 3.0 x 3.0 x 2.5 cm. The tumor is confined to the liver. The adjacent liver parenchyma shows mildly active steatohepatitis and bridging fibrosis (Stage 3). The liver parenchyma resection margin is negative for tumor (tumor free margin, 0.4 cm). Macroscopic large vessel invasion is absent. Microscopic invasion is absent. No regional lymph nodes identified.

AJCC stage (with available surgical material): pT1 (7th edition).

Seen in consultation with

Interpreted by:
Report electronically signed by
Transcribed by:

PRELIMINARY FROZEN SECTION CONSULTATION:

A. Liver, caudate lobe, resection: Hepatocellular carcinoma, moderately differentiated, forming a single mass, 3.0 x 3.0 x 2.5 cm. The tumor is confined to the liver. The liver parenchyma resection margin is negative for tumor (tumor free margin, 0.4 cm). Macroscopic large vessel invasion is absent. Microscopic invasion is absent. No regional lymph nodes identified. HOLD OVER to grade the tumor and evaluate the non-neoplastic liver tissue.

Frozen section histologic interpretation performed by:

GROSS DESCRIPTION:

A. Received fresh labeled "liver caudate lobe" is a 72.0 gram, 9.0 x 6.0 x 4.5 cm liver wedge specimen. A single 3.0 x 3.0 x 2.5 cm tan, yellow, and brown mass is present 0.4 cm from the inked surgical margin. Margin is submitted perpendicularly. Representative sections are submitted. Research tissue collected, Grossed by

BLOCK SUMMARY:

Part A: Liver-caudate lobe
1 Liver tumor with margin
2 Tumor with normal liver
3 Normal liver

Source: NCI Genomic Data Commons file 31761d88-bc2d-4e93-a3ff-84ee99bef1a4 (TCGA-DD-A73A.CAFC4E06-D637-463A-BBC8-D3B5E608204D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).